Surgical pathology report (de-identified scan), TCGA case TCGA-IB-AAUR, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-AAUR-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
		Location	

Copied To

Report Patient Name:
Demographics (for
verification purposes)
Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
A: Lymph node no 8 at
B: Portal lymph node at
C: Gallbladder at
D: Whipple specimen at
E: Pancreas at
Clinical Information
Pancreatic mass
Infectious patient: No
Immunocompromised: No
History of neoplasm: No

ICD O-3
Adenocarcinoma, duct NOS
8500/3
Site: Pancreas head
025.0
9/5/20/14

Diagnosis

- A. Lymph Node, #8, Excision:
- One lymph node involved by metastatic adenocarcinoma (1/1).
- B. Lymph Node, Portal, Excision:
- One lymph node, negative for malignancy (0/1).
- C. Gallbladder, Cholecystectomy:
- Chronic cholecystitis with mild activity.
- Cholesterosis.
- One cystic duct lymph node, negative for malignancy (0/1).
- D. Head of Pancreas and Duodenum, Whipple Resection:
- Invasive ductal adenocarcinoma, well differentiated with foamy gland pattern and large duct pattern, 3.7 x 3.5 x 3.5 cm.
- Lymphatic invasion, venous invasion, and perineural invasion present.
- Nine of twenty-one lymph nodes involved by metastatic adenocarcinoma (9/21).
- Adenocarcinoma involves common bile duct margin and retroperitoneal margin.
- Proximal and distal duodenal margins negative for malignancy.
- Please see comment and synoptic report.
- E. Pancreas, Neck Margin, Biopsy:
- Rare atypical cells, suspicious for adenocarcinoma.
- Please see comment.

Reported by:

Electronically signed by:

Verified:

[page 2 of 3]
Synoptic Report

SPECIMEN:

Head of pancreas

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension: 3.7 cm

Additional dimensions: 3.5 x 3.5 cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G1: Well differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades peripancreatic soft tissues

Tumor invades retroperitoneal soft tissue

Tumor invades extrapancreatic common bile duct

MARGINS:

Margin(s) involved by invasive carcinoma

Uncinate process (retroperitoneal) margin (nonperitonealized surface of the uncinate process)

Common bile duct margin

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

Number examined: 24

Number involved: 10

DISTANT METASTASIS (pM):

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS:

Chronic pancreatitis

CLINICAL HISTORY:

Not specified

Gross Description

Received are specimen containers A to E. All positions and specimen containers are labelled with the patient's name, The cassettes and identifiers are labelled with the Surgical Number

A: The specimen is received fresh and is subsequently placed into formalin. The container is designated "lymph node no 8" and contains a 2.5 x 1.0 x 0.5 cm firm tan yellow ovoid portion of tissue grossly consistent with a lymph node. On sectioning, the lymph node is firm, white, and grossly suspicious. The trisected lymph node is submitted entirely in A1 and A2.

B: The specimen is received fresh and is subsequently placed into formalin. The container is designated "portal lymph nodes" and contains an irregular heavily cauterized, 0.9 x 0.5 x 0.3 cm greyish tan tissue fragment. The fragment is bisected and submitted in toto in B1.

C: The specimen is received fresh and is subsequently placed into formalin. The container is designated "gallbladder" and contains an intact unopened 6.5 x 3.5 x 2.0 cm gallbladder. The gallbladder serosa is smooth and shiny without nodules or adhesions, and the adventitial surface is slightly roughened. The cystic duct is open. The cystic duct margin is inked black. A 0.8 x 0.6 x 0.5 cm plump ovoid cystic duct lymph node is present. The gallbladder lumen contains viscous green bile and no gallstones. The gallbladder wall is thin, pliable, and approximately 2 mm thick. The gallbladder mucosa is green and velvety with marked yellow speckling suggestive of cholesterosis. There are no polyps, masses or other lesions. Representative sections are submitted as follows:

C1. bisected cystic duct lymph node and black - inked cystic duct margin
C2. two representative sections of gallbladder mucosa, one from near gallbladder neck and

one from fundus

D: The specimen is received fresh and is subsequently placed into formalin. The container is designated "Whipple's specimen" and contains a 23 cm long portion of duodenum with attached 6.5 x 5.5 x 3.5 cm portion of the pancreatic head. The duodenum

[page 3 of 3]
has an average linear circumference of 4 cm, and the distal 13 cm of the duodenum shows dusky ischemic discoloration. The duodenal mucosa has the normal pattern of folds, without polyps or other lesions. The retroperitoneal margin (designated with a blue suture) is inked blue and the SMA groove is inked green, and the pancreatic neck margin is inked black. A portion of the pancreatic duct is identified at the pancreatic neck margin, but the duct appears occluded less than 1 cm from the margin. Replacing much of the head of the pancreas, there is an ill-defined roughly 3.7 x 3.5 x 3.5 cm firm rubbery tan white mass with infiltrative borders. On sectioning, the central portion of the mass contains numerous cystic spaces filled with thin clear mucin. Grossly, the mass abuts the retroperitoneal margin and the SMA groove but does not clearly involve those margins. The mass closely abuts the common bile duct, which contains a metal stent. The mass also approaches to the level of the ampulla, but does not invade the wall of the duodenum. Numerous lymph nodes are identified in the surrounding peripancreatic fat, a few of which are slightly enlarged and firm. Representative sections are submitted as follows:

- D1. proximal duodenal margin
- D2. distal duodenal margin
- D3. bile duct margin
- D4. tumor with pancreatic neck margin
- D5-7. three contiguous sections of tumor showing relationship of tumor with common bile duct and retroperitoneal margin
- D8. one lymph node bisected (represents the remainder of the lymph node previously sampled in B5), one additional possible lymph node inked blue and submitted whole
- D9. tumor with pancreatic margin
- D10. tumor with common bile duct and SMA groove
- D11. one peripancreatic lymph node trisected
- D12. section of tumor with bile duct
- D13. peripancreatic fat with possible lymph nodes
- D14. two lymph nodes (one node inked blue and bisected)
- D15. one node bisected
- D16. two lymph nodes (one node inked blue and trisected)
- D17. additional section of tumor with bile duct and ampulla
- D18-19. central portion of tumor with cystically dilated spaces filled with mucin
- D20. one lymph node trisected
- D21. two lymph nodes (one node bisected, one node inked blue submitted whole)
- D22-25. additional peripancreatic fat with possible lymph nodes
- E: The specimen consists of pink tan tissue measuring 2.2 x 1 x 0.3 cm. Submitted in toto in E1.
- The specimen is received fresh for intraoperative consultation in a container designated "pancreas neck". The previously frozen tissue is entirely resubmitted for permanent sections in EQS1.

Frozen Section Diagnosis

E: Pancreatic Neck:

- Chronic inflammation with some dilated ducts. No malignancy in the sampled sections.

Reported by:

Pathologist Comment

E. Permanent sections of the pancreatic neck margin (i.e. slide E1-2) reveal rare crushed atypical cells, present in pools of mucin surrounding a nerve, highly suspicious for adenocarcinoma. These cells are not definitively identified in the original frozen section slides. Since the frozen section represents the "true" margin, and the permanent sections are cut from deeper (more distal) tissue, it is estimated that the true pancreatic neck margin is negative but that tumor extends very close (likely 1-2 mm) to this margin.

In case ancillary studies are desired, tumor block information is listed below:

Best tumor block: D9

Best normal block: C2

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file 245b91ae-1b80-4778-bce2-0cc812d63411 (TCGA-IB-AAUR.D7C86FB0-811D-4B63-A8DF-E8A7BFB117C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).